MMRF case MMRF_1541 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/b09aab3d-c7ed-49b8-814a-c4218d72f5aa

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 57 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 57.7 years (21,080 days); ISS stage: III; Days to last known disease status: 1,290 days (3.5 years); Days to last follow up: 1,290 days (3.5 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 2 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 561 days (1.5 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 337 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 8 days; Days to treatment end: 367 days (1.0 years).
   Treatment given: Therapeutic agents: Pomalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 379 days (1.0 years); Days to treatment end: 561 days (1.5 years).
   Treatment given: Therapeutic agents: Other; Regimen or line of therapy: Third line of therapy; Days to treatment start: 561 days (1.5 years); Days to treatment end: 645 days (1.8 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Fourth line of therapy; Days to treatment start: 676 days (1.9 years); Days to treatment end: 860 days (2.4 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Fifth line of therapy; Days to treatment start: 889 days (2.4 years).
   Treatment given: Therapeutic agents: Daratumumab; Regimen or line of therapy: Fifth line of therapy; Days to treatment start: 902 days (2.5 years); Days to treatment end: 1,308 days (3.6 years).
   Treatment given: Therapeutic agents: Daratumumab; Regimen or line of therapy: Sixth line of therapy; Days to treatment start: 1,308 days (3.6 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Sixth line of therapy; Days to treatment start: 1,309 days (3.6 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -44 (ECOG 2): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.41 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1885 mg/dL; Immunoglobulin G 88.8 g/L; Immunoglobulin A 0.19 g/L; Immunoglobulin M 0.06 g/L; Beta 2 Microglobulin 15.3 µg/mL; Hemoglobin 6.2 mmol/L; Leukocytes 10.1 ×10⁹/L; Absolute Neutrophil 4.8 ×10⁹/L; Platelets 124 ×10⁹/L; Creatinine 129 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 1.68 mmol/L; Albumin 27 g/L; Total Protein 12.3 g/dL; Glucose 5.34 mmol/L; C-Reactive Protein 0.051 mg/dL.
- Day 37 (ECOG 2): M Protein 4.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.98 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1196 mg/dL; Immunoglobulin G 63.4 g/L; Immunoglobulin A 0.2 g/L; Immunoglobulin M 0.14 g/L; Beta 2 Microglobulin 14 µg/mL; Lactate Dehydrogenase 7.27 µkat/L; Hemoglobin 5.95 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 53 ×10⁹/L; Creatinine 160 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.25 mmol/L; Albumin 38 g/L; Total Protein 10.5 g/dL; Glucose 4.24 mmol/L.
- Day 127 (ECOG 2): M Protein 3.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.03 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 303 mg/dL; Immunoglobulin G 45.7 g/L; Immunoglobulin A 0.48 g/L; Immunoglobulin M 0.15 g/L; Beta 2 Microglobulin 8.16 µg/mL; Lactate Dehydrogenase 6.33 µkat/L; Hemoglobin 6.01 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 41 ×10⁹/L; Creatinine 136 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.35 mmol/L; Albumin 35 g/L; Total Protein 8.9 g/dL; Glucose 7.7 mmol/L.
- Day 232 (ECOG 1): M Protein 4 g/dL; Immunoglobulin G 61.3 g/L; Immunoglobulin A 0.12 g/L; Immunoglobulin M 0.09 g/L; Hemoglobin 7.69 mmol/L; Leukocytes 7.2 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 36 ×10⁹/L; Creatinine 130 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.33 mmol/L; Albumin 35 g/L; Total Protein 9.9 g/dL; Glucose 6.44 mmol/L.
- Day 302 (ECOG 1): M Protein 3.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.06 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 714 mg/dL; Immunoglobulin G 42.4 g/L; Immunoglobulin A 0.31 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 6.02 µg/mL; Lactate Dehydrogenase 8.17 µkat/L; Hemoglobin 5.52 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 11 ×10⁹/L; Creatinine 141 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.35 mmol/L; Albumin 41 g/L; Total Protein 8.9 g/dL; Glucose 5.39 mmol/L.
- Day 400 (ECOG 1): M Protein 3.7 g/dL; Hemoglobin 7.75 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 0.9 ×10⁹/L; Platelets 27 ×10⁹/L; Creatinine 149 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.25 mmol/L; Albumin 37 g/L; Total Protein 9.6 g/dL; Glucose 7.1 mmol/L.
- Day 491 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.67 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 257 mg/dL; Immunoglobulin G 48.3 g/L; Immunoglobulin A 0.26 g/L; Immunoglobulin M 0.11 g/L; Beta 2 Microglobulin 8.8 µg/mL; Hemoglobin 8.18 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 44 ×10⁹/L; Creatinine 129 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.15 mmol/L; Albumin 35 g/L; Total Protein 9.1 g/dL; Glucose 12.2 mmol/L.
- Day 582 (ECOG 1): M Protein 3.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.55 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 454 mg/dL; Immunoglobulin G 48 g/L; Immunoglobulin A 0.41 g/L; Immunoglobulin M 0.09 g/L; Beta 2 Microglobulin 6.74 µg/mL; Lactate Dehydrogenase 8.4 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 27 ×10⁹/L; Creatinine 131 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.23 mmol/L; Albumin 37 g/L; Total Protein 9.5 g/dL; Glucose 8.31 mmol/L.
- Day 666 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 0.81 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 309 mg/dL; Immunoglobulin G 46.6 g/L; Immunoglobulin A 0.18 g/L; Immunoglobulin M 0.14 g/L; Hemoglobin 7.13 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 12 ×10⁹/L; Creatinine 149 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.2 mmol/L; Albumin 38 g/L; Total Protein 9.4 g/dL; Glucose 5.12 mmol/L.
- Day 750 (ECOG 1): M Protein 3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.51 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 383 mg/dL; Immunoglobulin G 44.3 g/L; Immunoglobulin A 0.08 g/L; Immunoglobulin M 0.15 g/L; Beta 2 Microglobulin 8.13 µg/mL; Hemoglobin 7.87 mmol/L; Leukocytes 8.8 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 20 ×10⁹/L; Creatinine 144 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 1.98 mmol/L; Albumin 32 g/L; Total Protein 8.7 g/dL; Glucose 8.09 mmol/L.
- Day 842 (ECOG 1): M Protein 2.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.39 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 245 mg/dL; Immunoglobulin G 35.3 g/L; Immunoglobulin A 0.4 g/L; Immunoglobulin M 1.25 g/L; Hemoglobin 8.62 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 28 ×10⁹/L; Creatinine 128 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.2 mmol/L; Albumin 32 g/L; Total Protein 7.8 g/dL; Glucose 17.3 mmol/L.
- Day 940 (ECOG 1): M Protein 2.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.78 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 279 mg/dL; Immunoglobulin G 28.9 g/L; Immunoglobulin A 0.4 g/L; Immunoglobulin M 0.25 g/L; Hemoglobin 7.75 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 71 ×10⁹/L; Creatinine 90.2 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.23 mmol/L; Albumin 32 g/L; Total Protein 7.5 g/dL; Glucose 6.66 mmol/L.
- Day 1,031 (ECOG 1): M Protein 2.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.73 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 234 mg/dL; Immunoglobulin G 24.4 g/L; Immunoglobulin A 0.4 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 11 µg/mL; Lactate Dehydrogenase 8.07 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 8.9 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 42 ×10⁹/L; Creatinine 159 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 8.5 g/dL; Glucose 11.1 mmol/L.
- Day 1,115 (ECOG 1): M Protein 2.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.44 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 191 mg/dL; Immunoglobulin G 28 g/L; Immunoglobulin A 0.4 g/L; Immunoglobulin M 0.25 g/L; Hemoglobin 9.11 mmol/L; Leukocytes 9.5 ×10⁹/L; Absolute Neutrophil 6.1 ×10⁹/L; Platelets 72 ×10⁹/L.
- Day 1,199: M Protein 2.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.283 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 443 mg/dL; Immunoglobulin G 25.5 g/L; Immunoglobulin A 0.0429 g/L; Immunoglobulin M 0.12 g/L; Hemoglobin 8.31 mmol/L; Leukocytes 10.7 ×10⁹/L; Absolute Neutrophil 7.4 ×10⁹/L; Platelets 81 ×10⁹/L; Creatinine 118 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.15 mmol/L; Albumin 35 g/L; Total Protein 7.8 g/dL; Glucose 14.8 mmol/L.
- Day 1,290 (ECOG 1): M Protein 4.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.347 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2630 mg/dL; Immunoglobulin G 45.5 g/L; Immunoglobulin A 0.023 g/L; Immunoglobulin M 0.12 g/L; Beta 2 Microglobulin 11.3 µg/mL; Lactate Dehydrogenase 7.88 µkat/L; Hemoglobin 6.08 mmol/L; Leukocytes 7.2 ×10⁹/L; Absolute Neutrophil 2.57 ×10⁹/L; Platelets 30 ×10⁹/L; Creatinine 210 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.28 mmol/L; Albumin 39 g/L; Total Protein 11.1 g/dL; Glucose 9.9 mmol/L.

Other clinical attributes
- Day -44: Weight: 106 kg; Height: 175 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1541_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -44 days.
- Sample MMRF_1541_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -44 days.
